Somatic mutation profile of tumor specimen ALCH-B3K4-TTP1-A (aliquot ALCH-B3K4-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3K4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.3 years (21,284 days).
Specimen ALCH-B3K4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8943e8f-a292-4607-9bce-7010e7f4919a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3K4-NB1-A (Blood Derived Normal), aliquot ALCH-B3K4-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b6836f5-1241-4317-9124-97848cd29532

The open-access MAF lists 114 somatic variants for this specimen: 70 protein-altering or splice-affecting, 26 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 26, Intron 10, RNA 3, 3'UTR 3, 5'UTR 2, Nonsense Mutation 2, Frame Shift Ins 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 183/729 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ARAP3 | c.2807G>A p.R936Q | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1304061025, COSV53356734; called by muse, mutect2, varscan2
- CALCRL | c.436A>G p.I146V | Missense Mutation (SNP) | VAF 22/466 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.129); catalogued as rs867380403; called by muse, mutect2
- CASC3 | c.957C>G p.F319L | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.057); catalogued as COSV52869051; called by muse, mutect2
- DAPL1 | c.90dup p.Q31Tfs*35 | Frame Shift Ins (INS) | VAF 72/326 reads (22%) | catalogued as rs1419018289; called by mutect2, pindel, varscan2
- EXT2 | c.626G>T p.R209M (on ENST00000343631; = p.R242M on NM_000401.3) | Missense Mutation (SNP) | VAF 24/764 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV59153348; called by muse, mutect2
- GCFC2 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs976431787; called by muse, mutect2
- HIF1A | c.2113G>T p.E705* | Nonsense Mutation (SNP) | VAF 14/312 reads (4%) | catalogued as COSV60188781; called by muse, mutect2
- IFT80 | c.1004A>G p.D335G | Missense Mutation (SNP) | VAF 132/1134 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as rs1452018167; called by muse, mutect2, varscan2
- LHX6 | c.793-3C>T | Splice Region (SNP) | VAF 23/337 reads (7%) | catalogued as rs916389695; called by muse, mutect2
- MAP2K3 | c.496C>A p.L166I (on ENST00000342679 / NM_145109.3; = p.L137I on NM_002756.4) | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.099); catalogued as COSV57575894; called by muse, mutect2
- NALCN | c.2470G>T p.E824* | Nonsense Mutation (SNP) | VAF 13/317 reads (4%) | catalogued as rs1337798493; called by muse, mutect2
- NAMPT | c.332A>G p.H111R | Missense Mutation (SNP) | VAF 130/595 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs370987898; called by muse, mutect2, varscan2
- OR2C3 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 130/625 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs139293334; called by muse, mutect2, varscan2
- PIK3CG | c.2804A>C p.Y935S | Missense Mutation (SNP) | VAF 36/755 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63245484; called by muse, mutect2
- PRSS56 | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as rs900612557; called by muse, mutect2
- RCSD1 | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 92/692 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as rs376910996; called by muse, varscan2
- REG3A | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 79/415 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs764419758; called by muse, mutect2, varscan2
- RNF213 | c.10528_10529del p.E3510Kfs*3 | Frame Shift Del (DEL) | VAF 172/860 reads (20%) | catalogued as rs1164544832; called by mutect2, pindel, varscan2
- SCN11A | c.4484C>A p.P1495H | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56565301; called by muse, mutect2
- SDAD1 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 113/477 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.077); catalogued as rs1560536867; called by muse, mutect2, varscan2
- SEMA6C | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 15/295 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1254191269, COSV59006389; called by muse, mutect2
- SYNM | c.4587G>C p.K1529N (on ENST00000336292 / NM_145728.3; = p.K1217N on NM_015286.6) | Missense Mutation (SNP) | VAF 28/562 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs1555486252; called by muse, mutect2
- TAF1 | c.3532C>T p.R1178W (on ENST00000373790 / NM_138923.4; = p.R1199W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52116682; called by muse, mutect2
- TBX5 | c.220A>G p.M74V | Missense Mutation (SNP) | VAF 48/966 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs1555226577, CM075031; called by muse, mutect2
- THOC2 | c.4225C>T p.R1409C | Missense Mutation (SNP) | VAF 159/661 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773323309, COSV55541985, COSV55545868; called by muse, mutect2, varscan2
- TRERF1 | c.2605C>T p.R869W | Missense Mutation (SNP) | VAF 19/457 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs988927395; called by muse, mutect2
- UTP15 | c.1534G>C p.E512Q | Missense Mutation (SNP) | VAF 19/310 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV57147856, COSV99707734; called by muse, mutect2
- VPS13A | c.3028C>G p.L1010V | Missense Mutation (SNP) | VAF 30/637 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1337056764; called by muse, mutect2
- WAS | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 34/694 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1557007058, COSV100939440, COSV64996604; called by muse, mutect2
- ZNF236 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 60/1207 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs368542736; called by muse, mutect2
- ABCB6 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- ANKRD30BL | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 17/426 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, mutect2
- BIRC2 | c.1480G>C p.D494H | Missense Mutation (SNP) | VAF 18/446 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, mutect2
- BRWD3 | c.1870G>T p.A624S | Missense Mutation (SNP) | VAF 35/789 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.145); called by muse, mutect2
- C9orf131 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 14/407 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.445); called by muse, mutect2
- CASKIN1 | c.1148C>A p.A383E | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- CCDC180 | c.3177C>A p.S1059R | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- CELF4 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CYP4F3 | c.148T>C p.C50R | Missense Mutation (SNP) | VAF 23/426 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2
- DNAH14 | c.3992G>A p.C1331Y (on ENST00000445597; = p.C1741Y on NM_001367479.1) | Missense Mutation (SNP) | VAF 28/510 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.198); called by muse, mutect2
- DOCK3 | c.131G>C p.R44T | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPOP | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2
- EXT1 | c.2201C>G p.S734C | Missense Mutation (SNP) | VAF 48/1328 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- FANCM | c.5461C>G p.L1821V | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- GRIN3A | c.2216G>C p.C739S | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2
- GZF1 | c.1196T>A p.V399E | Missense Mutation (SNP) | VAF 84/264 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNA5 | c.992G>T p.C331F | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- KCNC3 | c.1976C>A p.A659E | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.362); called by muse, mutect2
- KCTD18 | c.690G>C p.E230D | Missense Mutation (SNP) | VAF 28/793 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- KIDINS220 | c.2692C>G p.L898V | Missense Mutation (SNP) | VAF 148/710 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- MARF1 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 34/792 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.657); called by muse, mutect2
- MED12 | c.941G>T p.S314I | Missense Mutation (SNP) | VAF 40/265 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- MTO1 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2
- NEUROD4 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 50/1248 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2
- PIGG | c.1959G>A p.M653I (on ENST00000453061 / NM_001127178.3; = p.M645I on NM_017733.4) | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- PLPBP | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 76/209 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RUNDC3A | c.684C>G p.S228R | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2
- S100PBP | c.533G>C p.G178A | Missense Mutation (SNP) | VAF 30/572 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); called by muse, mutect2
- SAGE1 | c.1688T>C p.V563A | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2
- SH2B1 | c.2140G>A p.A714T | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); called by muse, mutect2
- SLAMF7 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SLC9A9 | c.1097A>C p.E366A | Missense Mutation (SNP) | VAF 23/537 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- TDP1 | c.1361A>G p.Y454C | Missense Mutation (SNP) | VAF 64/1392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TENM1 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 46/1352 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.136); called by muse, mutect2
- TGM2 | c.1092G>C p.K364N | Missense Mutation (SNP) | VAF 18/371 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- TMEM144 | c.662A>G p.Y221C | Missense Mutation (SNP) | VAF 42/434 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- TPST2 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); called by muse, mutect2
- USP42 | c.324A>T p.R108S | Missense Mutation (SNP) | VAF 41/798 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.437); called by muse, mutect2
- ZC3HAV1 | c.385C>G p.L129V | Missense Mutation (SNP) | VAF 78/399 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BTN2A2 | c.888G>C p.L296= | Silent (SNP) | VAF 24/692 reads (3%) | called by muse, mutect2
- CAMTA2 | c.1149C>T p.S383= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- CCDC168 | c.9519A>C p.S3173= | Silent (SNP) | VAF 9/167 reads (5%) | called by muse, mutect2
- CFAP74 | c.3564C>G p.L1188= | Silent (SNP) | VAF 16/268 reads (6%) | catalogued as rs1465668742; called by muse, mutect2
- CLPTM1L | c.330C>T p.L110= | Silent (SNP) | VAF 98/662 reads (15%) | called by muse, mutect2, varscan2
- CPLANE2 | c.60G>A p.E20= | Silent (SNP) | VAF 17/355 reads (5%) | catalogued as rs1486928641; called by muse, mutect2
- DSCAM | c.3924G>A p.K1308= | Silent (SNP) | VAF 30/523 reads (6%) | catalogued as COSV101261568; called by muse, mutect2
- FAR1 | c.921A>T p.T307= | Silent (SNP) | VAF 30/614 reads (5%) | called by muse, mutect2
- GCG | c.138G>A p.Q46= | Silent (SNP) | VAF 16/606 reads (3%) | catalogued as rs1418417454, COSV64962108; called by muse, mutect2
- GLI2 | c.663G>A p.P221= | Silent (SNP) | VAF 38/572 reads (7%) | catalogued as rs760171656, COSV58050296; called by muse, mutect2
- GRIN2C | c.1914C>A p.I638= | Silent (SNP) | VAF 32/486 reads (7%) | catalogued as rs1347773560; called by muse, mutect2
- IGHV4-28 | c.240C>T p.N80= | Silent (SNP) | VAF 214/1145 reads (19%) | catalogued as rs782735266; called by muse, varscan2
- KCNK18 | c.495G>C p.R165= | Silent (SNP) | VAF 28/660 reads (4%) | called by muse, mutect2
- MPZL3 | c.642G>A p.A214= | Silent (SNP) | VAF 192/793 reads (24%) | catalogued as rs113204504; called by muse, mutect2, varscan2
- NAV2 | c.1371C>G p.P457= (on ENST00000396087 / NM_001244963.2; = p.P434= on NM_145117.5) | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV62333778; called by muse, mutect2
- NKAIN2 | c.351G>A p.V117= | Silent (SNP) | VAF 21/364 reads (6%) | called by muse, mutect2
- NNAT | c.57C>T p.F19= | Silent (SNP) | VAF 102/430 reads (24%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.930C>T p.F310= | Silent (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- RBBP8 | c.1008C>T p.I336= | Silent (SNP) | VAF 26/449 reads (6%) | called by muse, mutect2
- RHOF | c.579C>T p.L193= | Silent (SNP) | VAF 17/282 reads (6%) | catalogued as COSV99932222; called by muse, mutect2
- SDF2L1 | c.18C>T p.R6= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- SEPTIN9 | c.1638G>A p.Q546= (on ENST00000427177 / NM_001113491.2; = p.Q528= on NM_006640.4) | Silent (SNP) | VAF 71/267 reads (27%) | called by muse, mutect2, varscan2
- TNRC6C | c.423C>T p.N141= | Silent (SNP) | VAF 53/257 reads (21%) | catalogued as rs755156990; called by muse, mutect2, varscan2
- VN1R5 | c.993G>T p.L331= | Silent (SNP) | VAF 38/388 reads (10%) | called by muse, mutect2, varscan2
- ZFP3 | c.204C>T p.D68= | Silent (SNP) | VAF 26/570 reads (5%) | called by muse, mutect2
- ZNF697 | c.1605C>T p.H535= | Silent (SNP) | VAF 26/102 reads (25%) | called by muse, varscan2
- ASB2 | c.908+3346C>G | Intron (SNP) | VAF 23/410 reads (6%) | called by muse, mutect2
- ATP11A | c.*26G>A | 3'UTR (SNP) | VAF 98/371 reads (26%) | called by muse, mutect2, varscan2
- C9orf129 | n.640C>G | RNA (SNP) | VAF 104/440 reads (24%) | called by muse, mutect2, varscan2
- EIF2B4 | c.705+31C>T | Intron (SNP) | VAF 29/444 reads (7%) | called by muse, mutect2
- FMR1 | c.*1465A>G | 3'UTR (SNP) | VAF 18/644 reads (3%) | called by muse, mutect2
- GP6 | c.*529C>A | 3'UTR (SNP) | VAF 41/1185 reads (3%) | called by muse, mutect2
- HTR2C | c.-80+17035G>T | Intron (SNP) | VAF 56/117 reads (48%) | called by muse, mutect2, varscan2
- IGLV2-8 | c.-15C>G | 5'UTR (SNP) | VAF 14/446 reads (3%) | catalogued as rs1462368843; called by muse, mutect2
- LINC02035 | n.232C>G | RNA (SNP) | VAF 42/885 reads (5%) | called by muse, mutect2
- NAA10 | c.387-42G>C | Intron (SNP) | VAF 152/714 reads (21%) | called by muse, mutect2, varscan2
- PRAMEF1 | c.866+459T>G | Intron (SNP) | VAF 12/366 reads (3%) | called by muse, mutect2
- PXMP2 | c.519+1189C>A | Intron (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- SIPA1L1 | c.-302-13961G>C | Intron (SNP) | VAF 24/716 reads (3%) | called by muse, mutect2
- SPART | c.-3+1890T>C | Intron (SNP) | VAF 18/246 reads (7%) | catalogued as rs1195103945; called by muse, mutect2
- TENM2 | c.503-120933G>A | Intron (SNP) | VAF 14/176 reads (8%) | catalogued as rs755054318, COSV101585692; called by muse, mutect2
- TEX21P | n.1454G>A | RNA (SNP) | VAF 28/895 reads (3%) | called by muse, mutect2
- TUBA3C | c.-21G>C | 5'UTR (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- ZNF683 | c.-12+174A>T | Intron (SNP) | VAF 102/434 reads (24%) | catalogued as rs1160739900; called by muse, mutect2, varscan2
